Somatic mutation profile of tumor specimen TARGET-10-PARFDL-09A (aliquot TARGET-10-PARFDL-09A-01D) from TARGET case TARGET-10-PARFDL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 20.5 years (7,491 days).
Specimen TARGET-10-PARFDL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c738a6f-a82f-41aa-aefe-5b09d0e55bc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFDL-10A (Blood Derived Normal), aliquot TARGET-10-PARFDL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63ccdcc6-53e0-4715-9357-0e0f9c03773f

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, 5'UTR 2, Splice Region 1, RNA 1, Splice Site 1, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX1 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53131535; called by muse, mutect2, varscan2
- CYP24A1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143934667, CM150019; called by muse, mutect2, varscan2
- KDF1 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57670893; called by muse, mutect2, varscan2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- OPLAH | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782092864, COSV70677172; called by muse, mutect2, varscan2
- PHF6 | c.720del p.Y240* (on ENST00000332070 / NM_032458.3; = p.Y241* on NM_032335.3) | Frame Shift Del (DEL) | VAF 59/85 reads (69%) | catalogued as COSV59699738, COSV59705400; called by mutect2, pindel, varscan2
- SLC25A33 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV57019203; called by muse, varscan2
- TRPV4 | c.2354G>T p.W785L | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55680224; called by muse, varscan2
- TUBB8 | c.167-4G>A | Splice Region (SNP) | VAF 7/33 reads (21%) | catalogued as rs782716579; called by muse, varscan2
- VSTM4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as rs563816877, COSV53677039; called by muse, varscan2
- BCL11B | c.1391_1392insTCCCGGGGG p.C464_S465insPGG (on ENST00000357195 / NM_001282237.2; = p.C393_S394insPGG on NM_022898.3 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- CCDC136 | c.1991C>A p.S664Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- OR4K2 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC7A1 | c.1678-1G>T p.X560_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- STARD7 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- COL22A1 | c.3093G>C p.G1031= | Silent (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- KRT34 | c.225G>A p.G75= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs1395278804; called by muse, varscan2
- MOG | c.519C>A p.L173= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- NEUROG2 | c.534C>T p.G178= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs758924537; called by muse, mutect2, varscan2
- PKDCC | c.435C>T p.G145= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2
- SLC19A3 | c.384C>T p.Y128= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as rs746490830; called by mutect2, varscan2
- THBS1 | c.1206C>T p.R402= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs376255871; called by muse, mutect2, varscan2
- ZMYND8 | c.558G>A p.A186= (on ENST00000311275 / NM_001363741.2; = p.A206= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs746673431, COSV99521391; called by muse, mutect2, varscan2
- C4orf50 | c.-820C>T | 5'UTR (SNP) | VAF 33/73 reads (45%) | catalogued as rs771845184, COSV100135814; called by muse, varscan2
- LMF1 | c.*725G>T | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- MARCKS | c.-56G>A | 5'UTR (SNP) | VAF 37/73 reads (51%) | catalogued as rs1382662194; called by mutect2, varscan2
- OR56B3P | n.318T>G | RNA (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
